Somatic mutation profile of tumor specimen MMRF_2541_1_BM_CD138pos (aliquot MMRF_2541_1_BM_CD138pos_T1_KHS5U_K15152) from MMRF case MMRF_2541, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.7 years (21,081 days).
Specimen MMRF_2541_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fc07e6f-56db-449a-987f-b88035f5605f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2541_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2541_1_PB_Whole_C3_KHS5U_K15151; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92b467a1-5286-44bb-97d7-f2ea738a5989

The open-access MAF lists 98 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 29, Silent 14, Intron 12, Nonsense Mutation 2, Splice Region 2, Frame Shift Ins 2, Frame Shift Del 2, 5'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 49/105 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHCYL1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs375992787; called by muse, mutect2, varscan2
- DIP2C | c.3257C>T p.T1086M | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55155487; called by muse, mutect2, varscan2
- DNAH11 | c.11933A>G p.K3978R | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.691); catalogued as COSV60982915; called by muse, mutect2, varscan2
- GFPT2 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 95/299 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs751766251; called by muse, mutect2, varscan2
- IGHV1-69 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 102/364 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs544777113; called by muse, varscan2
- IGHV2-70 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs757180345; called by muse, varscan2
- IGHV2-70 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 128/192 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.162); catalogued as rs184814603; called by muse, varscan2
- INHA | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199544141; called by muse, mutect2, varscan2
- KCNJ18 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1207745076; called by muse, mutect2, varscan2
- LRRIQ3 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 36/71 reads (51%) | catalogued as COSV63040877; called by muse, mutect2, varscan2
- LZTS2 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs535080900; called by muse, mutect2, varscan2
- OR2A12 | c.316T>C p.F106L | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs766870056; called by muse, mutect2, varscan2
- PACS2 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.421); catalogued as COSV100330932; called by muse, mutect2, varscan2
- PCDHAC1 | c.2315G>A p.R772H | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs782298445; called by muse, mutect2, varscan2
- PCDHGC5 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1562137380; called by muse, mutect2, varscan2
- PNLIPRP3 | c.917C>A p.S306Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100982434, COSV65047087; called by muse, mutect2, varscan2
- RSU1 | c.288C>G p.N96K | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs776590449; called by muse, mutect2, varscan2
- SLC16A9 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs757539013; called by muse, mutect2
- TENM3 | c.7805C>T p.A2602V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as rs371499646; called by muse, mutect2, varscan2
- APC2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- APOB | c.8406A>C p.E2802D | Missense Mutation (SNP) | VAF 85/167 reads (51%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- BIRC6 | c.12589G>A p.G4197R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRD2 | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C4BPA | c.1662A>T p.R554S | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DACH2 | c.949del p.M317* | Frame Shift Del (DEL) | VAF 54/241 reads (22%) | called by mutect2, varscan2
- DIS3L | c.1231G>A p.V411M (on ENST00000319212 / NM_001143688.3; = p.V328M on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 214/323 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DNAH14 | c.10106A>G p.E3369G (on ENST00000445597; = p.E4377G on NM_001367479.1) | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- DNAH3 | c.5727del p.I1911Sfs*7 | Frame Shift Del (DEL) | VAF 66/154 reads (43%) | called by mutect2, varscan2
- DOCK3 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 145/149 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DYNC2H1 | c.1771G>C p.A591P | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EML5 | c.3879C>A p.G1293= | Splice Region (SNP) | VAF 57/83 reads (69%) | called by muse, mutect2, varscan2
- EYS | c.2538C>A p.C846* | Nonsense Mutation (SNP) | VAF 195/310 reads (63%) | called by muse, mutect2, varscan2
- GPLD1 | c.182dup p.A62Gfs*7 | Frame Shift Ins (INS) | VAF 47/193 reads (24%) | called by mutect2, pindel, varscan2
- HTR2A | c.224dup p.N75Kfs*46 | Frame Shift Ins (INS) | VAF 60/146 reads (41%) | called by mutect2, varscan2
- IGHV1-69 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- LRCH2 | c.2143T>G p.F715V | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NTS | c.339C>A p.S113R | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PABPN1 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TRIO | c.4423+8A>T | Splice Region (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2
- ALX4 | c.153C>T p.A51= | Silent (SNP) | VAF 64/288 reads (22%) | called by muse, mutect2, varscan2
- ELANE | c.441C>T p.N147= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs146878885; called by muse, mutect2, varscan2
- FBL | c.546T>C p.G182= | Silent (SNP) | VAF 44/132 reads (33%) | called by muse, varscan2
- GPR158 | c.1554T>C p.I518= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2
- HHIPL1 | c.2079C>T p.G693= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as rs1325264794; called by muse, mutect2, varscan2
- HOMER3 | c.441C>T p.N147= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV55355581; called by muse, mutect2
- IGHV2-70 | c.252G>A p.L84= | Silent (SNP) | VAF 66/183 reads (36%) | catalogued as rs374732396; called by muse, varscan2
- IGLV3-1 | c.171G>A p.K57= | Silent (SNP) | VAF 68/216 reads (31%) | catalogued as rs191197478; called by muse, varscan2
- KALRN | c.6570C>T p.P2190= (on ENST00000360013 / NM_001024660.4; = p.P493= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/137 reads (40%) | called by muse, mutect2, varscan2
- KANK4 | c.2616C>T p.T872= | Silent (SNP) | VAF 70/148 reads (47%) | called by muse, mutect2, varscan2
- NKX3-1 | c.519G>A p.Q173= | Silent (SNP) | VAF 113/247 reads (46%) | called by muse, mutect2, varscan2
- RASAL1 | c.2197C>T p.L733= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs1290269712; called by muse, mutect2, varscan2
- RGMA | c.258G>A p.T86= | Silent (SNP) | VAF 54/174 reads (31%) | catalogued as rs56039462; called by muse, mutect2, varscan2
- SIK3 | c.939A>G p.L313= (on ENST00000445177 / NM_001366686.2; = p.L319= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 116/223 reads (52%) | called by muse, mutect2, varscan2
- ABHD2 | c.*534G>A | 3'UTR (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- AKIRIN1 | c.*1354C>T | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- C11orf97 | c.*104dup | 3'UTR (INS) | VAF 20/43 reads (47%) | catalogued as rs904252320; called by mutect2, varscan2
- CCDC82 | c.*679T>C | 3'UTR (SNP) | VAF 53/110 reads (48%) | called by muse, mutect2, varscan2
- CFL2 | c.*96C>T | 3'UTR (SNP) | VAF 23/204 reads (11%) | called by muse, mutect2, varscan2
- COL5A2 | c.*1370G>T | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- CTAGE13P | chr6:168293804 C>T | 5'Flank (SNP) | VAF 6/13 reads (46%) | catalogued as rs1363705190; called by muse, mutect2, varscan2
- DACH2 | c.1751-2693A>G | Intron (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- FAM216B | c.*1390C>G | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- FCRLA | c.131-25C>T | Intron (SNP) | VAF 8/128 reads (6%) | catalogued as rs1298924230; called by muse, mutect2
- FOSL2 | c.*639C>T | 3'UTR (SNP) | VAF 39/76 reads (51%) | catalogued as rs917973896; called by muse, mutect2, varscan2
- FRAT2 | c.*1115_*1116dup | 3'UTR (INS) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.*3536G>T | 3'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- FSTL5 | c.*549A>G | 3'UTR (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- HERC4 | c.226+3173A>G | Intron (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- HLA-DMA | c.653-52G>A | Intron (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- HPGD | c.*690C>A | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- KDM2B | c.1735-14021G>T | Intron (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- KPNA1 | c.*4205T>C | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- MLN | c.*116C>A | 3'UTR (SNP) | VAF 20/183 reads (11%) | called by muse, mutect2, varscan2
- MOB3B | c.*3212C>T | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- MYF5 | c.*560A>G | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- NCOR2 | c.1149+182A>T | Intron (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- OGT | c.*337G>A | 3'UTR (SNP) | VAF 40/102 reads (39%) | called by muse, mutect2, varscan2
- OOSP3 | chr11:59898495 G>A | 3'Flank (SNP) | VAF 66/345 reads (19%) | called by muse, mutect2, varscan2
- PAWR | c.*779A>G | 3'UTR (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- PRRG3 | c.*1111G>T | 3'UTR (SNP) | VAF 170/354 reads (48%) | called by muse, mutect2, varscan2
- PTGFR | c.*473A>G | 3'UTR (SNP) | VAF 43/95 reads (45%) | catalogued as rs929754186; called by muse, mutect2, varscan2
- RAB14 | c.*2960C>T | 3'UTR (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- RNF145 | c.-40+1671C>G | Intron (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.*1139G>C | 3'UTR (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- SLMAP | c.1336+1544G>T | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- STK16 | c.657+89A>T | Intron (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2, varscan2
- TBX18 | c.*290G>A | 3'UTR (SNP) | VAF 79/118 reads (67%) | called by muse, varscan2
- TBX18 | c.-200C>T | 5'UTR (SNP) | VAF 96/306 reads (31%) | catalogued as rs1424773235; called by muse, mutect2, varscan2
- THY1 | c.*170C>T | 3'UTR (SNP) | VAF 27/107 reads (25%) | catalogued as COSV99411622; called by muse, mutect2, varscan2
- TMED2 | c.*1309G>T | 3'UTR (SNP) | VAF 9/48 reads (19%) | catalogued as rs553325949, COSV99147705; called by muse, mutect2, varscan2
- TNIK | c.*633C>T | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- TNNT2 | c.234-143C>T | Intron (SNP) | VAF 9/32 reads (28%) | catalogued as rs746399794; called by muse, mutect2, varscan2
- UBE2H | c.*473C>A | 3'UTR (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- VAMP2 | c.*1477C>G | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- WASL | c.*2042C>T | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- XKR4 | c.806+61303G>T | Intron (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- ZNF24 | c.568+897del | Intron (DEL) | VAF 37/91 reads (41%) | called by mutect2, pindel, varscan2
